Somatic mutation profile of tumor specimen 0DMKNA from CCDI case PBCAPD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.6 years (3,490 days).
Specimen 0DMKNA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03857d87-c482-4552-ab0e-2a4936df135b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMKKM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/101e82e6-9818-4b71-9b7f-59080e8ca34c

The open-access MAF lists 16 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, Intron 1, 5'Flank 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFG1L | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs532639912, COSV64555826; called by muse, mutect2, varscan2
- COL5A2 | c.361G>T p.V121L | Missense Mutation (SNP) | VAF 91/342 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.147); catalogued as COSV66411265; called by muse, mutect2
- ERAS | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs782285333; called by muse, mutect2, varscan2
- NFKB1 | c.2617G>A p.V873M (on ENST00000394820 / NM_001382627.1; = p.V874M on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs995077819; called by muse, mutect2, varscan2
- OTUD7A | c.1957C>G p.R653G (on ENST00000307050 / NM_001382637.1; = p.R646G on NM_130901.3) | Missense Mutation (SNP) | VAF 92/215 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61044503; called by muse, mutect2, varscan2
- PDILT | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 251/432 reads (58%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.87); catalogued as COSV56705405; called by muse, mutect2, varscan2
- RIN1 | c.346_348del p.F116del | In Frame Del (DEL) | VAF 67/319 reads (21%) | catalogued as rs1565202523; called by mutect2, pindel, varscan2
- REEP6 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- ALPL | c.570C>T p.N190= | Silent (SNP) | VAF 129/406 reads (32%) | catalogued as rs760153868, COSV66379470; called by muse, mutect2, varscan2
- B3GNT9 | c.1140C>T p.H380= | Silent (SNP) | VAF 24/430 reads (6%) | catalogued as rs1159918609, COSV99531638; called by muse, mutect2
- COL6A6 | c.5667C>T p.G1889= | Silent (SNP) | VAF 222/372 reads (60%) | catalogued as rs776769919; called by muse, mutect2, varscan2
- MAPK8IP1 | c.255C>T p.S85= | Silent (SNP) | VAF 12/216 reads (6%) | called by muse, mutect2
- SATL1 | c.897G>A p.P299= (on ENST00000395409; = p.P486= on NM_001012980.2) | Silent (SNP) | VAF 104/106 reads (98%) | catalogued as rs780858954; called by muse, varscan2
- FUT7 | chr9:137034950 A>G | 5'Flank (SNP) | VAF 79/195 reads (41%) | called by muse, mutect2, varscan2
- PRDM16 | c.2940-55C>T | Intron (SNP) | VAF 46/170 reads (27%) | catalogued as rs1326495343; called by muse, mutect2, varscan2
- TSR2 | c.-15del | 5'UTR (DEL) | VAF 48/81 reads (59%) | catalogued as rs1192878776; called by mutect2, pindel, varscan2
